Surgical pathology report (de-identified scan), TCGA case TCGA-21-1075, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-1075-01A (Primary Tumor).

[page 1 of 3]
Clinical History/Diagnosis: Left Lung CA

Source of Specimen(s):

A: Portion of sixth Rib

B: Cytology

C: Level 9 Lymph Node

D: Level 5 Lymph Node

E: Level 10 Lymph Node

F: Level 6 Lymph Node

G: Left Lung

H: Left Level 7 Lymph Node

Gross Description:

Source of Tissue: 1. Protocol Specimen

Source of Tissue: 2. Cytology Specimen

Source of Tissue: 3. Labeled #3, "level 9 lymph node"

Gross Description: Received fresh is a fragment of yellow-tan fibrofatty tissue measuring 1.5 x 1.2 x 0.3 cm. The specimen is bisected to reveal two potential lymph nodes measuring from 0.4 up to 0.8 cm in its greatest dimension. The lymph nodes are submitted in one block.

Designation of Sections: Block 3

Summary of Sections: undesignated-2

Source of Tissue: 4. Labeled #4, "level 5 lymph nodes"

Gross Description: Received fresh are multiple fragments of gray-tan anthracotic pigmented soft tissue fragments measuring 2.4 x 1.7 x 0.6 cm in aggregate. The specimen is submitted in toto in one block.

Designation of Sections: Block 4

Summary of Sections: undesignated-multiple

[page 2 of 3]
Source of Tissue: 5. Labeled #5, "level 10 lymph nodes"

Gross Description: Received fresh is a gray-black anthracotic pigmented soft tissue fragment measuring 2.0 x 1.3 x 0.5 cm. The specimen is bisected and submitted in toto in one block.

Designation of Sections: Block 5

Summary of Sections: undesignated-2

Source of Tissue: 6. Labeled #6, "level 6 lymph nodes"

Gross Description: Received fresh is a gray-black anthracotic pigmented soft tissue fragment measuring 1.7 x 1.0 x 0.4 cm. The specimen is bisected and submitted in toto in one block.

Designation of Sections: Block 6

Summary of Sections: undesignated-2

Source of Tissue: 7. Labeled #7, "left lung"

Gross Description: Received fresh is a left pneumonectomy weighing 933.3 grams and measuring 16.0 x 17.5 x 6.5 cm having a red-purple pleura surface with diffuse anthracotic pigmentation. Located in the left lower lobe is a mass which distorts the lower lobe of the lung. The bronchus measures 3.5 cm in length with a diameter of 1.6 cm. The specimen is serially sectioned to reveal a well circumscribed gray-tan necrotic mass measuring 11.0 x 5.8 cm in its greatest dimension. The bronchial tree is opened to reveal mucus. The hilar region is dissected to reveal eleven potential lymph nodes. Representative sections are submitted in nine blocks.

Designation of Sections: 7A-7I

Summary of Sections: 7A- bronchial margin, 7B- vascular margin, 7C-7E- eleven hilar lymph nodes, 7F-7G- representative sections of the tumor, 7H- the tumor in relation to the bronchi, 7I- adjacent lung parenchyma

Source of Tissue: 8. Labeled #8, "left level 7 lymph node"

Gross Description: Received fresh are two gray-tan-black anthracotic pigmented soft tissue fragments measuring 3.5 x 2.5 x 1.0 cm in aggregate. The specimen is serially sectioned and submitted in toto in four blocks.

Designation of Sections: 8A-8D

[page 3 of 3]
Summary of Sections: multiple

Final Diagnosis:

1. Portion of 6th rib:

- Taken for protocol.

2. Cytology

3. Level 9 lymph nodes, excision:

- Three lymph nodes negative for tumor (0/3).

4. Level 5 lymph nodes, excision:

- Five lymph nodes all negative for tumor (0/5).

5. Level 10 lymph nodes, excision:

- One lymph node positive for microscopic metastatic carcinoma (1/1).

6. Level 6 lymph nodes, excision:

- One lymph node negative for tumor (0/1).

7. Left lung, pneumonectomy:

- Moderately differentiated keratinizing squamous cell carcinoma, 11.0cm.
- Visceral pleural, bronchial and vascular margins are negative for tumor.
- One out of twelve peribronchial lymph nodes positive for metastatic carcinoma(1/12).

8. Level 7 lymph nodes, excision:

- Five lymph nodes all negative for tumor (0/5).

Pathology stage of the tumor is pT2 N1

Source: NCI Genomic Data Commons file b5d82c7a-78fe-4480-afd1-f85b26b01219 (TCGA-21-1075.8B3A07B0-B34E-4D70-B8BE-7BB6BB30395A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).